CCDI case PBCNZI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/47e84700-0277-4eff-ac3a-df5fde765b65

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 5.5 years (2,003 days).

Biospecimens (2 samples)
- Sample 0DWYUO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWYWI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
